Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EI, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EI-01A (Primary Tumor).

[page 1 of 2]
Date of surgery :

Right eye enucleation

Macroscopy

The eyeball measures 25 by 23 by 2 mm with a posterior segment of optic nerve of 9 mm of length and 3 mm in diameter. At the surface there is an extrasclerale extension of 4 mm. Samples have been made for cryopreservation. At the section, presence of a black tumor measuring 19 by 18 by 10 mm. The specimen has been entirely included in 14 blocks.

Microscopy

The tumor seen macroscopically correspond to a choroidal melanoma. This tumor proliferation is made of epithelioid (97%) and fusiform (3%) cells gathering in diffuse sheets or tumor cluster in a poor quantity of stroma heavily vascularised. Tumor cells present marked cytonuclear atypias. Cytoplasm contain rarely some melanin pigment. The mitotic index is estimated at 10 mitosis at the 40 magnification.

The tumor invades the sclera with the presence of extrasclerale extension.

Presence of tumor embolus in the vessels with tumor cells around the nerve ending.

Absence of tumor extension to the iris or ciliary body

There is an associated retinal detachment

The prelaminar and post laminar optic nerve as well as the optic foramen and the cut end are free

The meningeal sheaths are free

Conclusion

Melanoma with epithelioid and fusiform cells

Size of the tumor: 19 by 18 mm

The tumor invades the sclera with focal extra sclera extension

Presence of tumor embolus as well as tumor cells around the nerve ending

Absence of tumor extension to the ciliary body and the iris

The optic nerve , the meningeal sheaths and the cut end of the optic nerve are free.

C6CF 100.0.3
Melanoma, epithelioid cell
path 8771/3
Melanoma, epithelioid + spindle
cell mixed 8770/3
Site @ Choroid C69.3
MD 3/10/14

See path discrepancy form for epithelioid
and spindle cell ratio.

Conclusion

Melanoma with epithelioid and fusiform cells

Size of the tumor: 19 by 18 mm

The tumor invades the sclera with focal extra sclera extension

Presence of tumor embolus as well as tumor cells around the nerve ending

Absence of tumor extension to the ciliary body and the iris

The optic nerve , the meningeal sheaths and the cut end of the optic nerve are free.

HPV Discrepancy		✓
Qual/Synch/Genous Primary/Noted		✓

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	97% epithelioid cells 3% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% epithelioid cells 1-30% spindle cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 5471412d-aec4-473c-8942-f7d230ba2cb4 (TCGA-V4-A9EI.E7477E21-C96C-4003-92C3-86896441757A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).